Somatic mutation profile of tumor specimen TCGA-DU-7012-01A (aliquot TCGA-DU-7012-01A-11D-2024-08) from TCGA case TCGA-DU-7012, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 74.0 years (27,039 days).
Specimen TCGA-DU-7012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7cf5f84-7460-4188-b6bc-6ef6272c69ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7012-10A (Blood Derived Normal), aliquot TCGA-DU-7012-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9371e3f-8800-4922-af26-27e400f0fad9

The open-access MAF lists 66 somatic variants for this specimen: 44 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 39, Silent 22, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.70G>C p.G24R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV55937401; called by muse, mutect2, varscan2
- ADGRG4 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs201466383, COSV99794238; called by muse, mutect2, varscan2
- AFM | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs771719904, COSV56919283, COSV56920023; called by muse, mutect2, varscan2
- BPIFB3 | c.1149C>T p.S383= | Splice Region (SNP) | VAF 14/46 reads (30%) | catalogued as rs1258902609, COSV64956793; called by muse, mutect2, varscan2
- BTBD11 | c.1930G>A p.V644I (on ENST00000280758 / NM_001018072.2; = p.V181I on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as rs151233634; called by muse, mutect2
- CACNA1A | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64202274; called by muse, mutect2, varscan2
- CCDC114 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs370475371; called by muse, mutect2
- CCN5 | c.710G>C p.C237S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51937899; called by muse, mutect2, varscan2
- CFTR | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV50066911; called by muse, mutect2, varscan2
- CHMP4C | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs528902989, COSV51927708; called by muse, mutect2, varscan2
- CILP2 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1373214564, COSV52276580; called by muse, mutect2
- DDI1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs138983347, COSV56380960; called by muse, mutect2, varscan2
- DPPA5 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1238480576, COSV64875723, COSV64875816; called by muse, mutect2, varscan2
- EGFR | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51774829, COSV51792876; called by muse, mutect2, varscan2
- FAT2 | c.8777C>T p.A2926V | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs377736336; called by muse, mutect2, varscan2
- FBN3 | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs113517176, COSV54464802; called by muse, mutect2, varscan2
- FLNA | c.3679G>A p.G1227R | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61042937; called by muse, mutect2, varscan2
- FUT10 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368379310, COSV59451060; called by muse, mutect2, varscan2
- GPR179 | c.2255G>A p.R752H (on ENST00000621958; = p.R751H on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs373293115; called by muse, mutect2
- HEPACAM2 | c.722C>A p.P241H (on ENST00000394468 / NM_001039372.4; = p.P229H on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59061488; called by muse, mutect2, varscan2
- HSPG2 | c.3397C>T p.R1133C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747640970, COSV65973493; called by muse, mutect2, varscan2
- IL9R | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV54900593; called by muse, mutect2
- KCNB1 | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.025); catalogued as COSV65569184; called by muse, mutect2, varscan2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2, varscan2
- KNOP1 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV54928812; called by muse, mutect2, varscan2
- MACC1 | c.2015G>T p.G672V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60544253; called by muse, mutect2, varscan2
- MUC17 | c.9278C>T p.T3093I | Missense Mutation (SNP) | VAF 119/574 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60289218, COSV60293549; called by muse, mutect2, varscan2
- MYOCD | c.1319G>C p.S440T | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.352); catalogued as COSV58506518; called by muse, mutect2, varscan2
- NFATC1 | c.422T>A p.V141E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV53703348; called by muse, mutect2, varscan2
- NIT2 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs183950946, COSV67630147; called by muse, mutect2, varscan2
- NRROS | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs765330021, COSV60746583, COSV60747832; called by muse, mutect2, varscan2
- OR5M3 | c.643T>A p.S215T | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV56567362; called by muse, mutect2, varscan2
- PCDHGA5 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as rs753242901, COSV53976375; called by muse, mutect2, varscan2
- PEG3 | c.2536A>G p.S846G | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55635414, COSV55648644; called by muse, mutect2, varscan2
- PTEN | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64299161; called by muse, mutect2, varscan2
- SHKBP1 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as COSV52541147; called by muse, mutect2, varscan2
- SLC27A4 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55960575; called by muse, mutect2, varscan2
- SLC7A3 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs757626640, COSV53228069; called by muse, mutect2, varscan2
- TSGA10IP | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs1196709031, COSV73245333; called by muse, mutect2, varscan2
- VGLL4 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as rs1435825968, COSV56078649; called by muse, mutect2, varscan2
- VPS13C | c.4924G>A p.A1642T (on ENST00000644861 / NM_020821.3; = p.A1599T on NM_017684.5) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV51280621; called by muse, mutect2, varscan2
- ZCCHC4 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as COSV57182012; called by muse, mutect2, varscan2
- DDIT4 | c.573del p.L192Cfs*17 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- MRPL41 | c.264del p.A89Rfs*? | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- AC109583.1 | c.615C>T p.N205= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs374975497; called by muse, mutect2, varscan2
- ADAMTS20 | c.2097C>T p.H699= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs772793771, COSV67134191; called by muse, mutect2
- ATP8A2 | c.2316G>A p.A772= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs757284272, COSV54961024, COSV99680579; called by muse, mutect2, varscan2
- CCDC134 | c.618C>A p.R206= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV55388358; called by muse, mutect2, varscan2
- CLEC14A | c.792C>T p.D264= | Silent (SNP) | VAF 63/171 reads (37%) | catalogued as COSV60563149; called by muse, mutect2, varscan2
- DMRT2 | c.1236C>T p.T412= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV52402386; called by muse, mutect2, varscan2
- GATA1 | c.312C>T p.Y104= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs1557020183, COSV64962614; called by muse, mutect2, varscan2
- GPATCH3 | c.567G>A p.L189= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV64652280; called by muse, mutect2, varscan2
- HIF1A | c.864C>T p.T288= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2
- HUWE1 | c.1416G>A p.P472= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs145017919, COSV53352389; ClinVar: likely benign; called by muse, varscan2
- JAKMIP1 | c.2061C>T p.A687= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1014672820, COSV68953903; called by muse, mutect2, varscan2
- MS4A7 | c.267T>C p.F89= | Silent (SNP) | VAF 47/169 reads (28%) | catalogued as COSV55730604; called by muse, mutect2, varscan2
- OR51L1 | c.660T>C p.Y220= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV58625122; called by muse, mutect2, varscan2
- PGR | c.1029G>T p.R343= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV54804474; called by muse, mutect2, varscan2
- POLR2C | c.594C>T p.P198= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs770233003, COSV54673408; called by muse, mutect2, varscan2
- RGS11 | c.708G>A p.A236= (on ENST00000397770 / NM_183337.3; = p.A215= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs944418493, COSV51451613, COSV51452682, COSV99395600; called by muse, mutect2, varscan2
- SLC5A1 | c.1179C>T p.S393= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs201456202, COSV56686619; called by muse, mutect2, varscan2
- SLC8A2 | c.2211C>T p.F737= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs1389550086, COSV52638972; called by muse, mutect2, varscan2
- TCEAL3 | c.225G>A p.E75= | Silent (SNP) | VAF 47/211 reads (22%) | catalogued as COSV54580801; called by muse, mutect2, varscan2
- TMEM270 | c.598C>T p.L200= | Silent (SNP) | VAF 60/310 reads (19%) | catalogued as COSV57639142; called by muse, mutect2, varscan2
- UFSP1 | c.36G>A p.R12= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV53818933; called by muse, mutect2, varscan2
- ZNF280B | c.198G>A p.P66= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs749311271, COSV64529162; called by muse, mutect2, varscan2
